Somatic mutation profile of tumor specimen TCGA-L5-A4OR-01A (aliquot TCGA-L5-A4OR-01A-11D-A27G-09) from TCGA case TCGA-L5-A4OR, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IA; Tumor grade: GX; Age at diagnosis: 83.3 years (30,417 days).
Specimen TCGA-L5-A4OR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3348cef5-e595-4318-aa6c-3da954e40146.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A4OR-11A (Solid Tissue Normal), aliquot TCGA-L5-A4OR-11A-11D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c5b6917-0493-4300-8158-c40cc4b29c07

The open-access MAF lists 179 somatic variants for this specimen: 132 protein-altering or splice-affecting, 43 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 43, Nonsense Mutation 8, Splice Site 5, Frame Shift Del 4, Frame Shift Ins 3, Splice Region 2, 3'Flank 2, 3'UTR 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1F | c.1537C>T p.R513* | Nonsense Mutation (SNP) | VAF 38/42 reads (90%) | catalogued as rs1365490247, CM158285; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.1157G>T p.G386V | Missense Mutation (SNP) | VAF 13/26 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912580, CM021284, COSV61684421, COSV61688134, COSV61692671; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.439_444dup p.V147_D148dup | In Frame Ins (INS) | VAF 105/331 reads (32%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ABCA12 | c.6103T>G p.F2035V (on ENST00000272895 / NM_173076.3; = p.F1717V on NM_015657.3) | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1436843983; called by muse, mutect2, varscan2
- ADAMTS12 | c.3483A>C p.E1161D | Missense Mutation (SNP) | VAF 11/46 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV61261817; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1759C>G p.R587G | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54469608; called by muse, mutect2
- AGAP1 | c.1732G>A p.A578T (on ENST00000304032 / NM_001037131.3; = p.A525T on NM_014914.5) | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.998); catalogued as rs751791854; called by muse, mutect2, varscan2
- ALLC | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.908); catalogued as rs756768853, COSV52998569; called by muse, mutect2, varscan2
- ASL | c.617G>T p.G206V | Missense Mutation (SNP) | VAF 13/128 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs760559303, CM141283, COSV59188598; called by muse, mutect2
- ATP1A4 | c.276del p.T93Pfs*48 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs760258351; called by mutect2, pindel, varscan2
- BAZ2A | c.3203G>A p.R1068H | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.972); catalogued as rs535118194, COSV99465381; called by muse, mutect2, varscan2
- BCAM | c.133C>T p.R45* | Nonsense Mutation (SNP) | VAF 27/99 reads (27%) | catalogued as rs199665533; called by muse, mutect2, varscan2
- CACNA1D | c.2621+1G>A p.X874_splice (on ENST00000350061 / NM_001128840.3; = p.X894_splice on NM_000720.4) | Splice Site (SNP) | VAF 22/43 reads (51%) | catalogued as COSV55444715; called by muse, mutect2, varscan2
- CCIN | c.695C>T p.T232M | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.91); catalogued as rs147304766, COSV58725495; called by muse, mutect2, varscan2
- CLUL1 | c.1184C>G p.T395R | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.617); catalogued as rs762066087; called by muse, mutect2, varscan2
- COL22A1 | c.1804-2A>C p.X602_splice | Splice Site (SNP) | VAF 14/50 reads (28%) | catalogued as rs773749055; called by muse, mutect2, varscan2
- CPB1 | c.636T>G p.F212L | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as rs1336696762; called by muse, mutect2, varscan2
- DQX1 | c.1891C>T p.R631* | Nonsense Mutation (SNP) | VAF 6/60 reads (10%) | catalogued as rs755414819; called by muse, mutect2, varscan2
- DYRK4 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); catalogued as COSV50539324; called by muse, mutect2, varscan2
- EPS15L1 | c.667G>A p.V223I | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.121); catalogued as rs756438586; called by muse, mutect2, varscan2
- FBXO41 | c.1730G>A p.R577Q | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.11); PolyPhen benign (0.243); catalogued as rs374997955; called by muse, mutect2, varscan2
- FREM1 | c.872C>T p.P291L | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs746596765, COSV63087299; called by muse, mutect2, varscan2
- GAL3ST1 | c.599C>T p.P200L | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); catalogued as COSV100142895; called by muse, mutect2, varscan2
- GLDC | c.1084C>T p.R362C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs10975674; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HNRNPF | c.482C>T p.S161L | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100563289; called by muse, mutect2, varscan2
- IGLON5 | c.611C>T p.A204V | Missense Mutation (SNP) | VAF 29/56 reads (52%) | SIFT tolerated (0.3); PolyPhen benign (0.125); catalogued as rs1478891688, COSV54536011; called by muse, mutect2, varscan2
- JAKMIP3 | c.1279G>A p.V427M | Missense Mutation (SNP) | VAF 33/39 reads (85%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs1431051199, COSV53830935; called by muse, mutect2, varscan2
- KCNJ4 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57856883; called by muse, mutect2, varscan2
- KMT2B | c.2618G>A p.R873H | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs770865375; called by muse, varscan2
- LAMB2 | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs372230106, COSV59734867; called by muse, mutect2, varscan2
- LENG9 | c.1255G>A p.G419R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.084); catalogued as rs756283596; called by muse, mutect2, varscan2
- LRRK2 | c.2908C>A p.H970N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99040446; called by muse, mutect2, varscan2
- MAML2 | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs924131204; called by muse, mutect2
- MPHOSPH9 | c.1942G>A p.G648S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.02); catalogued as COSV100187117; called by muse, mutect2
- MYO18B | c.1559A>G p.Q520R | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV59143681; called by muse, mutect2, varscan2
- MYT1L | c.2703C>G p.L901= | Splice Region (SNP) | VAF 6/75 reads (8%) | catalogued as COSV67706595; called by muse, mutect2
- NAALADL2 | c.1465C>T p.R489* | Nonsense Mutation (SNP) | VAF 32/174 reads (18%) | catalogued as rs748708899; called by muse, mutect2, varscan2
- NES | c.1976C>A p.S659Y | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs555493675; called by muse, mutect2, varscan2
- OR52A1 | c.872A>G p.N291S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs948556302; called by muse, mutect2, varscan2
- PABPC5 | c.73T>G p.L25V | Missense Mutation (SNP) | VAF 22/25 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100442615; called by muse, mutect2, varscan2
- PARP8 | c.1229C>G p.S410C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV55865285; called by muse, mutect2, varscan2
- PCDHA11 | c.1970C>T p.A657V | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.036); catalogued as rs782763189; called by muse, mutect2, varscan2
- POC5 | c.598C>T p.H200Y (on ENST00000428202 / NM_001099271.2; = p.H175Y on NM_152408.2) | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs201679415; called by muse, mutect2, varscan2
- SGK3 | c.632G>A p.R211H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs550671159; called by muse, mutect2, varscan2
- SIM1 | c.1225A>C p.S409R | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV53490317; called by muse, mutect2, varscan2
- SLA | c.134G>A p.R45Q (on ENST00000338087 / NM_001045556.3; = p.R85Q on NM_006748.4) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs572664813, COSV55082496; called by muse, mutect2, varscan2
- SLC29A4 | c.322A>G p.M108V | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as rs149798710; called by muse, mutect2, varscan2
- TBX3 | c.1138G>A p.E380K (on ENST00000257566 / NM_016569.4; = p.E360K on NM_005996.4) | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.272); catalogued as rs865915137, CM994611, COSV57470534; called by muse, mutect2, varscan2
- TRPM3 | c.728A>C p.K243T (on ENST00000357533 / NM_001366142.2; = p.K88T on NM_020952.6) | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.226); catalogued as COSV100624521; called by muse, mutect2, varscan2
- TTN | c.7816G>A p.A2606T (on ENST00000591111; = p.A2560T on NM_003319.4) | Missense Mutation (SNP) | VAF 16/31 reads (52%) | PolyPhen probably damaging (0.966); catalogued as rs375286376; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- VWC2L | c.618G>T p.W206C | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV56978933; called by muse, mutect2, varscan2
- WDR64 | c.1144G>A p.V382I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs780558450, COSV63794241; called by muse, varscan2
- WNT5B | c.263G>A p.R88Q | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); catalogued as rs200966877; called by muse, mutect2, varscan2
- ZNF567 | c.1910G>T p.R637I (on ENST00000536254 / NM_001322913.1; = p.R606I on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs146394117; called by muse, mutect2, varscan2
- ZSWIM5 | c.1781C>T p.T594I | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.18); PolyPhen benign (0.022); catalogued as rs776875438, COSV62735574; called by muse, mutect2
- AAK1 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 35/79 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- ABCA12 | c.2475C>T p.S825= (on ENST00000272895 / NM_173076.3; = p.S507= on NM_015657.3) | Splice Region (SNP) | VAF 13/54 reads (24%) | called by muse, mutect2, varscan2
- ADAM22 | c.2505G>T p.W835C | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ALOX15B | c.831del p.L278Cfs*5 | Frame Shift Del (DEL) | VAF 32/105 reads (30%) | called by mutect2, pindel, varscan2
- ARHGEF3 | c.449_456del p.D150Afs*26 | Frame Shift Del (DEL) | VAF 7/44 reads (16%) | called by mutect2, pindel, varscan2
- C10orf90 | c.1741C>T p.P581S | Missense Mutation (SNP) | VAF 32/50 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C20orf194 | c.1357-1G>A p.X453_splice | Splice Site (SNP) | VAF 20/42 reads (48%) | called by muse, mutect2, varscan2
- CATSPERD | c.281G>A p.G94D | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- CBWD5 | c.470G>A p.G157E | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CLUL1 | c.592A>T p.S198C | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- COL5A3 | c.2559+1G>C p.X853_splice | Splice Site (SNP) | VAF 16/38 reads (42%) | called by muse, mutect2, varscan2
- COPS6 | c.485A>G p.D162G | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- CSMD3 | c.6176G>T p.S2059I (on ENST00000297405 / NM_001363185.1; = p.S1955I on NM_052900.3) | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- CSNK1A1 | c.449G>A p.C150Y | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- DCN | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.62); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DMXL2 | c.7375T>G p.Y2459D | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DUS3L | c.1531C>A p.Q511K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- EIF2B2 | c.424G>C p.V142L | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.021); called by muse, mutect2
- EVC | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 8/50 reads (16%) | called by muse, mutect2
- EYA1 | c.1256G>A p.C419Y | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FBXL20 | c.734_744del p.G245Vfs*28 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel
- FUBP3 | c.881G>A p.G294E | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- GOLGA4 | c.6349A>T p.T2117S | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GRIA1 | c.663G>C p.K221N | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- GRM8 | c.304A>G p.I102V | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- HERPUD2 | c.344C>T p.S115L | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- HIVEP2 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by mutect2, varscan2
- HMCN1 | c.5678C>G p.A1893G | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- INO80D | c.1027C>T p.Q343* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | called by muse, mutect2, varscan2
- IRF2BPL | c.1960C>T p.R654W | Missense Mutation (SNP) | VAF 12/22 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA9 | c.2968G>C p.G990R | Missense Mutation (SNP) | VAF 49/93 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IVL | c.1016A>G p.Q339R | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- KAT8 | c.10C>G p.Q4E | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- KCNQ3 | c.1494A>C p.E498D | Missense Mutation (SNP) | VAF 40/85 reads (47%) | SIFT tolerated (0.69); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- LPA | c.3514G>A p.D1172N | Missense Mutation (SNP) | VAF 42/135 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- LRIT1 | c.754C>A p.Q252K | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.86); PolyPhen benign (0.043); called by muse, mutect2
- MKNK2 | c.1016G>C p.C339S | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC6 | c.4065_4069dup p.T1357Rfs*101 | Frame Shift Ins (INS) | VAF 24/154 reads (16%) | called by mutect2, pindel, varscan2
- MYCBP2 | c.6947C>T p.P2316L (on ENST00000357337; = p.P2354L on NM_015057.5) | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MYCBP2 | c.2911G>T p.D971Y (on ENST00000357337; = p.D1009Y on NM_015057.5) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NAALADL2 | c.35C>A p.S12Y | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- OGFOD2 | c.275C>T p.A92V (on ENST00000228922 / NM_001304833.1; = p.A32V on NM_024623.3) | Missense Mutation (SNP) | VAF 23/48 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR2J3 | c.743T>G p.L248R | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2, varscan2
- OR6C74 | c.802T>A p.L268I | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PCDH9 | c.2713A>G p.S905G | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PCDHB16 | c.1289G>A p.R430K | Missense Mutation (SNP) | VAF 23/41 reads (56%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PDE8B | c.1544G>C p.R515T | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- PDZRN3 | c.2572G>A p.A858T | Missense Mutation (SNP) | VAF 37/72 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- PPFIA3 | c.3332G>T p.G1111V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2
- PRAG1 | c.884C>T p.S295F | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- PROX1 | c.1384C>A p.Q462K | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated (0.29); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RHBDF2 | c.2182C>T p.L728F | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- RHCG | c.457A>G p.I153V | Missense Mutation (SNP) | VAF 77/101 reads (76%) | SIFT tolerated (0.55); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- RPL7A | c.680dup p.N227Kfs*2 | Frame Shift Ins (INS) | VAF 20/52 reads (38%) | called by mutect2, pindel, varscan2
- SCN5A | c.1738A>C p.T580P | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.14); called by muse, mutect2
- SCNN1G | c.1501T>G p.L501V | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.716); called by muse, mutect2, varscan2
- SENP2 | c.40C>A p.R14S | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- SETX | c.836A>T p.D279V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- SHANK3 | c.655C>A p.P219T | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHROOM2 | c.4394A>T p.N1465I | Missense Mutation (SNP) | VAF 35/41 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SLC12A2 | c.3047A>T p.Q1016L | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STARD13 | c.2580G>A p.M860I (on ENST00000336934 / NM_001243476.3; = p.M742I on NM_052851.3) | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- TAF5L | c.271G>T p.E91* | Nonsense Mutation (SNP) | VAF 11/60 reads (18%) | called by muse, mutect2, varscan2
- TMEM255B | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TP53 | c.308_309dup p.Q104Tfs*20 | Frame Shift Ins (INS) | VAF 102/314 reads (32%) | called by mutect2, pindel, varscan2
- TRAM1L1 | c.335C>T p.T112I | Missense Mutation (SNP) | VAF 27/44 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); called by muse, mutect2, varscan2
- TRO | c.920G>T p.S307I | Missense Mutation (SNP) | VAF 24/29 reads (83%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPS1 | c.2337A>C p.K779N (on ENST00000220888 / NM_001330599.2; = p.K792N on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TTN | c.39763A>T p.K13255* (on ENST00000591111; = p.K5831* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 7/52 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.31987G>C p.A10663P (on ENST00000591111; = p.A9736P on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | PolyPhen benign (0.027); called by muse, mutect2, varscan2
- VWC2 | c.604G>A p.V202I | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- XIRP1 | c.292T>G p.F98V | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- XIRP2 | c.6769C>T p.H2257Y (on ENST00000628543; = p.H2432Y on NM_152381.6) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- ZFAT | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF528 | c.1068A>C p.E356D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF559 | c.34-2A>C p.X12_splice | Splice Site (SNP) | VAF 18/113 reads (16%) | called by muse, mutect2, varscan2
- ZNF570 | c.1525C>A p.Q509K | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- ABCC10 | c.408G>A p.L136= (on ENST00000372530 / NM_001198934.2; = p.L93= on NM_033450.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/44 reads (36%) | called by muse, mutect2, varscan2
- ABHD8 | c.843G>A p.T281= | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs777500896; called by muse, mutect2, varscan2
- ACSM3 | c.1036T>C p.L346= | Silent (SNP) | VAF 24/39 reads (62%) | catalogued as rs751545090; called by muse, mutect2, varscan2
- AOAH | c.726T>C p.V242= | Silent (SNP) | VAF 23/59 reads (39%) | called by muse, mutect2, varscan2
- AP002748.5 | c.1506C>T p.R502= | Silent (SNP) | VAF 45/87 reads (52%) | catalogued as rs756550025, COSV59149565; ClinVar: likely benign; called by muse, mutect2, varscan2
- B4GALNT3 | c.1986C>T p.N662= | Silent (SNP) | VAF 18/28 reads (64%) | catalogued as rs749123156; called by muse, mutect2, varscan2
- CACNA1E | c.5259A>G p.R1753= | Silent (SNP) | VAF 10/21 reads (48%) | catalogued as rs767215554; called by muse, varscan2
- CCDC158 | c.2958C>T p.D986= | Silent (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- CDH18 | c.1224A>G p.Q408= | Silent (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- CELSR2 | c.2571C>T p.G857= | Silent (SNP) | VAF 8/56 reads (14%) | catalogued as rs760728043, COSV54769776, COSV54781703; called by muse, mutect2, varscan2
- CNTNAP3 | c.57T>G p.T19= | Silent (SNP) | VAF 12/68 reads (18%) | called by muse, mutect2, varscan2
- CRTAC1 | c.213C>T p.I71= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs769375314, COSV54009674; called by muse, mutect2, varscan2
- DAPK2 | c.291C>T p.T97= | Silent (SNP) | VAF 7/62 reads (11%) | catalogued as rs541062258, COSV99977795; called by muse, mutect2, varscan2
- DHRS7C | c.561G>A p.P187= (on ENST00000330255 / NM_001220493.2; = p.P186= on NM_001105571.3) | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as rs892489854; called by muse, mutect2, varscan2
- GFRA1 | c.489C>T p.L163= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as rs766739399, COSV100816284; called by muse, mutect2, varscan2
- GLI1 | c.2328C>T p.T776= | Silent (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- HECTD1 | c.231C>T p.A77= | Silent (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- IER5 | c.792G>C p.G264= | Silent (SNP) | VAF 14/55 reads (25%) | called by muse, mutect2, varscan2
- KRI1 | c.519C>T p.D173= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs374028807; called by muse, varscan2
- KRT83 | c.789C>T p.S263= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as rs1350993256; called by muse, mutect2, varscan2
- LRP1B | c.10716T>C p.C3572= | Silent (SNP) | VAF 10/47 reads (21%) | called by muse, mutect2, varscan2
- LRRTM1 | c.462C>T p.P154= | Silent (SNP) | VAF 6/30 reads (20%) | catalogued as rs768455060; called by muse, mutect2, varscan2
- MPHOSPH9 | c.1941T>C p.C647= | Silent (SNP) | VAF 2/22 reads (9%) | called by muse, mutect2
- MUC16 | c.33408A>G p.E11136= | Silent (SNP) | VAF 36/87 reads (41%) | called by muse, mutect2, varscan2
- NELL1 | c.60G>A p.V20= | Silent (SNP) | VAF 26/42 reads (62%) | catalogued as COSV100125009; called by muse, mutect2, varscan2
- OR10K2 | c.351C>T p.V117= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV100149409, COSV100149637; called by muse, mutect2, varscan2
- OR51T1 | c.927C>A p.L309= | Silent (SNP) | VAF 13/34 reads (38%) | called by muse, mutect2, varscan2
- OR52K2 | c.396G>T p.L132= | Silent (SNP) | VAF 51/88 reads (58%) | catalogued as COSV100355803; called by muse, mutect2, varscan2
- PCDHA5 | c.168G>A p.A56= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs1554128345, COSV65348973; called by muse, mutect2, varscan2
- PHF21B | c.735G>A p.T245= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs147703835; called by muse, mutect2, varscan2
- PPFIA4 | c.2017A>C p.R673= (on ENST00000447715; = p.R674= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 17/40 reads (43%) | called by muse, mutect2, varscan2
- PRAMEF12 | c.204C>T p.S68= | Silent (SNP) | VAF 52/90 reads (58%) | called by muse, mutect2, varscan2
- PRAMEF14 | c.207G>A p.L69= | Silent (SNP) | VAF 20/55 reads (36%) | called by muse, mutect2, varscan2
- PSG11 | c.618T>C p.G206= | Silent (SNP) | VAF 114/264 reads (43%) | called by muse, mutect2, varscan2
- PUM2 | c.2382C>T p.A794= | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV57584379; called by muse, mutect2, varscan2
- RELN | c.1014G>T p.V338= | Silent (SNP) | VAF 41/108 reads (38%) | called by muse, mutect2, varscan2
- RO60 | c.1209C>G p.V403= | Silent (SNP) | VAF 5/45 reads (11%) | called by muse, mutect2, varscan2
- RXRA | c.984C>T p.T328= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as rs760095751, COSV104422983, COSV62684876; called by muse, mutect2, varscan2
- SEC14L5 | c.33C>A p.V11= | Silent (SNP) | VAF 43/68 reads (63%) | catalogued as COSV99229130; called by muse, mutect2, varscan2
- SSH3 | c.822G>A p.A274= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as rs201934241, COSV57383221; called by muse, mutect2, varscan2
- TAC4 | c.270G>A p.T90= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs781047699, COSV58004589; called by muse, mutect2, varscan2
- TBR1 | c.1035C>T p.D345= | Silent (SNP) | VAF 7/60 reads (12%) | called by muse, mutect2, varscan2
- USP17L2 | c.972C>G p.V324= | Silent (SNP) | VAF 18/145 reads (12%) | called by muse, mutect2, varscan2
- DCHS2 | n.6626C>A | RNA (SNP) | VAF 16/24 reads (67%) | called by muse, mutect2, varscan2
- KRT18P23 | chr22:44570535 C>A | 3'Flank (SNP) | VAF 15/27 reads (56%) | catalogued as rs1307460905; called by muse, mutect2, varscan2
- PRR23B | c.*1A>T | 3'UTR (SNP) | VAF 13/64 reads (20%) | called by muse, mutect2, varscan2
- SLCO2A1 | chr3:133928646 A>C | 3'Flank (SNP) | VAF 12/33 reads (36%) | called by muse, mutect2, varscan2
